Somatic mutation profile of tumor specimen TCGA-CR-6493-01A (aliquot TCGA-CR-6493-01A-11D-1870-08) from TCGA case TCGA-CR-6493, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.6 years (25,432 days).
Specimen TCGA-CR-6493-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75aa91e2-e6d6-4802-8ac3-ab89db6add5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6493-10A (Blood Derived Normal), aliquot TCGA-CR-6493-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1e0c021-7d39-4267-8e2f-b8b7dddb7d8c

The open-access MAF lists 33 somatic variants for this specimen: 30 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 2, Nonsense Mutation 2, RNA 1, In Frame Del 1, Frame Shift Ins 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- ABCB4 | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM075953, COSV99711234; called by muse, mutect2
- AJUBA | c.1216T>A p.C406S | Missense Mutation (SNP) | VAF 133/203 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52986212; called by muse, mutect2, varscan2
- ARMC6 | c.691C>T p.H231Y (on ENST00000392336; = p.H206Y on NM_033415.4) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV99523166; called by muse, mutect2, varscan2
- BOC | c.1327A>G p.R443G | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99849330; called by muse, mutect2, varscan2
- CACNA1E | c.6484G>A p.V2162I (on ENST00000367573 / NM_001205293.3; = p.V2119I on NM_000721.4) | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs373618053; called by muse, mutect2, varscan2
- CARD11 | c.1663dup p.R555Pfs*38 | Frame Shift Ins (INS) | VAF 22/98 reads (22%) | catalogued as rs762770988; called by mutect2, varscan2
- CDK11A | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100652117, COSV62266938; called by muse, mutect2
- COL11A1 | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100617962, COSV62181996; called by muse, mutect2, varscan2
- CYLD | c.1723A>T p.T575S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100282661, COSV100282750; called by muse, varscan2
- CYP27C1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs749430078, COSV100080026; called by muse, mutect2, varscan2
- DPY19L4 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV101363387; called by muse, mutect2, varscan2
- FAM90A1 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.79); catalogued as rs1332127328, COSV100274510; called by muse, mutect2, varscan2
- ISL2 | c.838C>G p.P280A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99320854; called by muse, mutect2, varscan2
- LTBP1 | c.5041T>C p.C1681R (on ENST00000404816 / NM_206943.4; = p.C1355R on NM_000627.4) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698796; called by muse, mutect2, varscan2
- MSRB1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs1320102820, COSV99238485; called by muse, mutect2, varscan2
- NKTR | c.1031C>G p.P344R | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99236306; called by muse, mutect2, varscan2
- NKTR | c.3084G>T p.E1028D | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.151); catalogued as COSV99236309; called by muse, mutect2, varscan2
- OR1N1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 47/80 reads (59%) | catalogued as rs563253378, COSV59195166; called by muse, mutect2, varscan2
- PCDHB8 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 154/196 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV50754259; called by muse, mutect2, varscan2
- PIP4K2C | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 148/312 reads (47%) | catalogued as COSV61606968; called by muse, mutect2, varscan2
- PLK4 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99584952; called by muse, mutect2, varscan2
- POLR2L | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV100431903; called by muse, mutect2, varscan2
- PREX1 | c.4811G>A p.R1604Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767487812, COSV64254197; called by muse, mutect2, varscan2
- PTPRC | c.2549T>C p.V850A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100723146; called by muse, mutect2, varscan2
- SACS | c.11933T>G p.L3978R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV101207713; called by muse, mutect2, varscan2
- CARMIL2 | c.309_314dup p.L104_E105insDL | In Frame Ins (INS) | VAF 20/64 reads (31%) | called by mutect2, pindel
- DNAJB11 | c.403_405del p.I135del | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by pindel, varscan2
- IGKV1-12 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 100/426 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- SP8 | c.93C>T p.H31= (on ENST00000361443 / NM_198956.4; = p.H49= on NM_182700.6) | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1014564346, COSV100815424; called by muse, mutect2, varscan2
- SUSD1 | c.720C>T p.G240= | Silent (SNP) | VAF 86/131 reads (66%) | catalogued as COSV100813486, COSV100813512; called by muse, mutect2, varscan2
- SLC35E2A | n.959C>A | RNA (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99870861; called by mutect2, varscan2
